Gene-level copy-number profile of tumor specimen TCGA-AN-A0FZ-01A from TCGA case TCGA-AN-A0FZ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 45.3 years (16,533 days).
Specimen TCGA-AN-A0FZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.522b6d2e-b8b1-46d0-b0cb-3823d574e549.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,741 have no estimate.
https://portal.gdc.cancer.gov/files/cc500c6e-6e07-452c-81d3-c661ba60188b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,548; copy number 2: 32,054; copy number 3: 7,705; copy number 4: 2,808; copy number 5: 1,795; copy number 6: 333; copy number 7: 639.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0FZ-01A-11D-A036-01): tumor purity 0.83, ploidy 2.23, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,767 genes in 49 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:67,092,165–67,231,853, 1 gene, copy number 6 (within-gene range 2–6): C1orf141.
- chr1:67,138,907–67,259,979, 2 genes, copy number 6 (within-gene range 2–6): IL23R, RNU6-586P.
- chr1:67,307,364–67,532,612, 4 genes, copy number 6: IL12RB2, SERBP1, RNU6-387P, LINC01702.
- chr1:67,656,831–68,538,627, 21 genes, copy number 6: RN7SL392P, HNRNPCP9, GADD45A, GNG12, RNU7-80P, GNG12-AS1, AL157407.1, DIRAS3, ARL5AP3, WLS, CTBP2P8, MIR1262, RPS7P4, COX6B1P7, ELOCP18, AL139413.1, RPE65, DEPDC1, AL138789.1, DEPDC1-AS1, TXNP2.
- chr1:85,318,481–85,708,433, 9 genes, copy number 6 (within-gene range 3–6): DDAH1, Y_RNA, AL360219.1, AC092807.3, AC092807.2, CCN1, SNORD81, AC092807.1, ZNHIT6.
- chr1:86,029,854–86,030,589, 1 gene, copy number 5: AC104455.1.
- chr1:88,477,828–88,498,676, 2 genes, copy number 5: RN7SL583P, AC093578.1.
- chr1:89,364,059–89,426,243, 3 genes, copy number 6: GBP6, CAPNS1P1, GBP1P1.
- chr1:92,508,696–92,792,404, 4 genes, copy number 5 (within-gene range 2–5): EVI5, AL354890.1, HMGB3P9, RNU4-59P.
- chr1:119,853,316–120,100,779, 4 genes, copy number 7: PFN1P9, NOTCH2P1, ADAM30, NOTCH2.
- chr7:16,087,525–25,949,986, 143 genes, copy number 5–7 (broad region; genes not listed).
- chr7:26,291,862–27,492,765, 63 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr7:28,953,358–33,877,180, 97 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:32,911,493–33,473,146, 10 genes, copy number 6: RNU6-663P, AC090204.1, MTND1P6, MTND2P32, RANP9, AC104027.1, RNU6-528P, AC067838.1, FUT10, AC091144.2.
- chr8:37,934,340–38,176,730, 14 genes, copy number 6: AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P.
- chr8:46,579,213–48,064,708, 41 genes, copy number 5: ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P, CEBPD, PRKDC, Y_RNA, AC021236.1, MCM4, RNU6-519P, UBE2V2.
- chr8:53,177,571–144,097,525, 1,369 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr10:16,513,734–17,911,164, 25 genes, copy number 5: C1QL3, AL353576.1, RSU1, AC073367.1, AL365215.1, AL365215.2, CUBN, AC067747.1, TRDMT1, VIM-AS1, VIM, AL133415.1, ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1.
- chr10:42,408,168–44,602,104, 67 genes, copy number 5–7 (broad region; genes not listed).
- chr10:57,955,295–58,831,435, 12 genes, copy number 6 (within-gene range 4–6): AC006484.1, MRPS35P3, AC026884.1, IPMK, TPT1P10, CISD1, AC016396.1, AC016396.2, UBE2D1, TFAM, BICC1, FAM133CP.
- chr10:59,088,701–62,268,844, 30 genes, copy number 7 (within-gene range 1–7): RPLP1P10, TRAF6P1, PHYHIPL, FAM13C, AC025038.1, AL355474.1, MRPL50P4, AC026391.1, SLC16A9, MRLN, CCDC6, LINC01553, ANK3, AL592430.1, Y_RNA, AL592430.2, ARL4AP1, ANK3-DT, CDK1, RHOBTB1, RNU2-72P, LINC00845, TMEM26, TMEM26-AS1, AL356952.1, CABCOCO1, AL451049.1, LINC02625, ARID5B, RTKN2.
- chr11:15,966,449–17,014,414, 9 genes, copy number 6 (within-gene range 3–6): SOX6, MIR6073, AC103794.1, AKR1B1P3, RN7SL188P, C11orf58, PLEKHA7, RN7SKP90, AC116533.1.
- chr11:35,132,655–35,232,402, 4 genes, copy number 6: AL356215.1, CD44, CD44-AS1, AL133330.1.
- chr11:72,114,869–79,612,300, 223 genes, copy number 6–7 (within-gene range 1–7) (broad region; genes not listed).
- chr11:80,321,620–82,718,299, 13 genes, copy number 6–7 (within-gene range 4–7): AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1.
- chr11:83,455,012–85,627,922, 4 genes, copy number 5 (within-gene range 1–7): DLG2, DLG2-AS2, AP002370.1, LDHAL6DP.
- chr11:84,639,993–89,295,759, 80 genes, copy number 6–7 (within-gene range 1–7) (broad region; genes not listed).
- chr12:62,021,570–63,055,765, 24 genes, copy number 5–7: RPS3P6, AC078789.1, KLF17P1, USP15, MIR6125, RNU6-595P, Metazoa_SRP, MON2, AC079035.1, RNU6-399P, LINC01465, AC048341.1, MIRLET7I, AC048341.2, PPM1H, RPL32P26, GAPDHP44, RNU1-83P, Y_RNA, RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5.
- chr12:64,338,178–65,663,299, 38 genes, copy number 5 (within-gene range 3–5): ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2.
- chr12:66,950,754–74,402,600, 126 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr12:76,315,751–78,540,675, 26 genes, copy number 5–7: RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1, AC025161.1, E2F7, AC079030.1, LINC02464, NAV3, AC073591.1, AC138331.1, AC073571.1, PRXL2AP1, LINC02424, AC128707.1, AC130415.1, AC079362.1.
- chr14:28,726,675–28,830,204, 6 genes, copy number 7 (within-gene range 3–7): FOXG1-AS1, AL049777.1, FOXG1, LINC01551, LINC02282, LINC02281.
- chr14:30,370,108–30,573,629, 3 genes, copy number 5 (within-gene range 4–5): AL079305.1, G2E3-AS1, AL117355.1.
- chr14:31,142,939–31,861,224, 16 genes, copy number 6 (within-gene range 4–6): RNU6-541P, Y_RNA, AL136418.1, Y_RNA, HEATR5A, ATP5MC1P2, AL139353.1, AL139353.2, DTD2, AL163973.1, GPR33, NUBPL, AL163973.3, AL163973.2, RNU6-602P, RNU6-455P.
- chr14:34,416,687–38,194,281, 91 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:42,072,752–43,550,954, 18 genes, copy number 6–7 (within-gene range 4–7): PTPRT, AL035666.1, AL031656.1, PTPRT-AS1, RN7SKP100, AL021395.1, RN7SL666P, PPIAP21, AL021395.2, AL031681.1, RNU6-743P, EIF4EBP2P1, Y_RNA, SRSF6, AL031681.2, RNU6-1251P, L3MBTL1, Z98752.2.
- chr20:51,386,957–55,684,915, 50 genes, copy number 5–7 (within-gene range 3–7): NFATC2, MIR3194, ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1, LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P, RPL12P4, LINC01440, LINC01441, AL160413.1.
- chr20:56,205,052–56,786,087, 23 genes, copy number 5: RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P.
- chr20:60,087,826–62,969,585, 69 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr21:46,072,085–46,286,297, 13 genes, copy number 6: PSMA6P3, AP001471.1, COL6A2, FTCD, FTCD-AS1, SPATC1L, AP001468.1, LSS, AP001469.1, MCM3AP-AS1, MCM3AP, AP001469.2, AP001469.3.

Autosomal genes at a single copy (total copy number 1): 9,548. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
